Somatic mutation profile of tumor specimen MP2PRT-PASHNC-TMP1-A (aliquot MP2PRT-PASHNC-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASHNC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,088 days).
Specimen MP2PRT-PASHNC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79d73130-330b-4c45-a17d-960725b3381b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASHNC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASHNC-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37887a17-bdbf-4fc9-92dc-75c00f2541a3

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397507507, CM060445, CM122799, COSV61005734; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSLN | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.068); catalogued as rs530021597; called by muse, mutect2, varscan2
- SPATS2L | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); catalogued as rs1333620477, COSV62353475; called by muse, mutect2
- USP9Y | c.4885A>C p.K1629Q | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DAG1 | c.222C>T p.V74= | Silent (SNP) | VAF 119/302 reads (39%) | catalogued as rs150727558; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GGT2 | c.1623C>T p.I541= | Silent (SNP) | VAF 73/705 reads (10%) | catalogued as rs1468469126; called by muse, varscan2
- MRPS35 | c.282C>T p.G94= | Silent (SNP) | VAF 38/364 reads (10%) | catalogued as rs1171541376; called by muse, mutect2, varscan2
- EYA2 | c.*151G>A | 3'UTR (SNP) | VAF 13/416 reads (3%) | catalogued as rs1430082077, COSV57942070; called by muse, mutect2
